Somatic mutation profile of tumor specimen MP2PRT-PASSAN-TMP1-A (aliquot MP2PRT-PASSAN-TMP1-A-1-0-D-A81N-36) from MP2PRT case MP2PRT-PASSAN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 7.8 years (2,849 days).
Specimen MP2PRT-PASSAN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 07ce81c4-e8cc-4431-bae6-ed5e23cd5638.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PASSAN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PASSAN-NB1-A-1-0-D-A81N-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/522e8ed1-fbe5-48ee-98aa-0b8e6f2966ec

The open-access MAF lists 24 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 6, Frame Shift Ins 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1H | c.6542C>T p.A2181V | Missense Mutation (SNP) | VAF 281/1032 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as rs776161185; called by muse, mutect2, varscan2
- MUC16 | c.33319G>T p.A11107S | Missense Mutation (SNP) | VAF 147/322 reads (46%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.179); catalogued as COSV67461016, COSV67469480; called by muse, mutect2, varscan2
- ONECUT2 | c.527C>T p.P176L | Missense Mutation (SNP) | VAF 442/1153 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as rs914841997; called by mutect2, varscan2
- PSMB11 | c.616C>T p.R206C | Missense Mutation (SNP) | VAF 59/681 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.304); catalogued as rs768517599, COSV57458972; called by muse, mutect2
- SLC25A41 | c.891G>C p.Q297H | Missense Mutation (SNP) | VAF 232/529 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58599578; called by muse, mutect2, varscan2
- TAF1L | c.10G>A p.G4S | Missense Mutation (SNP) | VAF 124/154 reads (81%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.01); catalogued as rs1261064270, COSV54256533; called by muse, mutect2, varscan2
- TMEM243 | c.295A>G p.I99V | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768990718; called by muse, mutect2, varscan2
- ATXN3 | c.1004C>T p.S335L | Missense Mutation (SNP) | VAF 180/471 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ITSN2 | c.2446dup p.M816Nfs*5 | Frame Shift Ins (INS) | VAF 96/291 reads (33%) | called by mutect2, pindel, varscan2
- LCOR | c.2929_2930insTTCCCCCAGGGAAACC p.E977Vfs*22 | Frame Shift Ins (INS) | VAF 108/326 reads (33%) | called by mutect2, pindel, varscan2
- MEPCE | c.1805G>C p.R602P | Missense Mutation (SNP) | VAF 232/506 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRPS9 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 152/387 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR5AR1 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 148/356 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- SLC40A1 | c.932G>A p.G311D | Missense Mutation (SNP) | VAF 156/388 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TCEAL6 | c.420G>A p.M140I | Missense Mutation (SNP) | VAF 238/670 reads (36%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- TEP1 | c.4899_4900dup p.D1634Gfs*31 | Frame Shift Ins (INS) | VAF 150/464 reads (32%) | called by pindel, varscan2
- ZNF157 | c.1471_1472insGGAA p.T491Rfs*69 | Frame Shift Ins (INS) | VAF 123/339 reads (36%) | called by mutect2, pindel, varscan2
- DST | c.7992A>C p.V2664= | Silent (SNP) | VAF 68/177 reads (38%) | called by muse, mutect2, varscan2
- KCND1 | c.93G>A p.P31= | Silent (SNP) | VAF 256/653 reads (39%) | catalogued as rs368004864, COSV54415720, COSV99501798, COSV99502109; called by muse, mutect2, varscan2
- NDUFB11 | c.291C>T p.I97= | Silent (SNP) | VAF 202/511 reads (40%) | called by muse, mutect2, varscan2
- PAQR9 | c.267G>A p.T89= | Silent (SNP) | VAF 242/580 reads (42%) | called by muse, mutect2, varscan2
- PCDHA6 | c.2115C>T p.C705= | Silent (SNP) | VAF 194/518 reads (37%) | catalogued as rs144997304; called by muse, mutect2, varscan2
- UBE2O | c.1290C>T p.A430= | Silent (SNP) | VAF 163/412 reads (40%) | catalogued as COSV100084004; called by muse, mutect2, varscan2
- EVL | c.352+9476del | Intron (DEL) | VAF 199/565 reads (35%) | called by mutect2, pindel, varscan2
